Somatic mutation profile of tumor specimen MMRF_2150_1_BM_CD138pos (aliquot MMRF_2150_1_BM_CD138pos_T1_KHS5U_L08684) from MMRF case MMRF_2150, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,157 days).
Specimen MMRF_2150_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25020270-ffea-438f-9a9e-9e003d0c865e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2150_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2150_1_PB_Whole_C2_KHS5U_L08685; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4054affb-a801-4025-89f2-dd56b8018884

The open-access MAF lists 150 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 50, Missense Mutation 38, Intron 17, Silent 17, 5'UTR 8, 3'Flank 5, RNA 4, 5'Flank 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFM | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769742032; called by muse, mutect2, varscan2
- ALKBH8 | c.1995A>G p.*665Wext*4 | Nonstop Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs1278517861; called by muse, mutect2, varscan2
- BCL6B | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs747779466, COSV99546544; called by muse, mutect2, varscan2
- BICRA | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1176748606; called by muse, mutect2, varscan2
- CLCN1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs748415883, COSV100577817; called by muse, mutect2, varscan2
- CTXN2 | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs1206133346; called by muse, mutect2, varscan2
- ENTPD8 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs578205858, COSV58161914; called by muse, mutect2, varscan2
- EPB42 | c.1004C>T p.T335M (on ENST00000441366 / NM_001114134.2; = p.T365M on NM_000119.3) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1363841649; called by muse, mutect2, varscan2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs755972268; called by mutect2, pindel
- IGHV2-70 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs370560636; called by muse, varscan2
- IGLL5 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.077); catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2, varscan2
- IGLV3-27 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs780041686; called by muse, mutect2, varscan2
- MSR1 | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV50507335, COSV50508675; called by muse, mutect2, varscan2
- NFE2L3 | c.1861_1862del p.K621Efs*7 | Frame Shift Del (DEL) | VAF 93/167 reads (56%) | catalogued as rs777869574, COSV50227502; called by mutect2, pindel, varscan2
- OR13C3 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 79/259 reads (31%) | catalogued as COSV66166191; called by muse, mutect2, varscan2
- PHPT1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs747681702; called by muse, mutect2, varscan2
- PLXNC1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748183392, COSV99313387; called by muse, mutect2, varscan2
- RASGRF1 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV69178595; called by muse, mutect2, varscan2
- ST3GAL3 | c.307C>T p.P103S (on ENST00000361392 / NM_174964.4; = p.P88S on NM_006279.5) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99495656; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | PolyPhen probably damaging (0.992); catalogued as rs894209375; called by muse, mutect2, varscan2
- STK32C | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs749645705; called by muse, mutect2, varscan2
- TTF1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1363518179; called by muse, mutect2, varscan2
- TTN | c.30154G>A p.E10052K (on ENST00000591111; = p.E9125K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/255 reads (47%) | PolyPhen benign (0.001); catalogued as rs886043278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBG1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52220693; called by muse, mutect2
- UBR4 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.353); catalogued as COSV100919951; called by muse, mutect2, varscan2
- VIL1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as COSV50287600; called by muse, mutect2, varscan2
- WDR26 | c.518G>A p.S173N (on ENST00000414423 / NM_001379403.1; = p.S73N on NM_025160.7) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.393); catalogued as rs1269360296; called by muse, mutect2, varscan2
- ZNF385B | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs753184978, COSV61176049; called by muse, mutect2, varscan2
- ADGRL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP11A | c.162+2T>A p.X54_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2
- ATP6V1B2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2 | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FKBP1C | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGHV1-69D | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- IGHV1-69D | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by mutect2, varscan2
- IGHV2-70D | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, varscan2
- IGHV2-70D | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, varscan2
- IL1RAPL2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.889); called by muse, mutect2
- IRF2BP2 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2C | c.637+1G>A p.X213_splice | Splice Site (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- MTMR1 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6N2 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- OTUD6A | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 71/75 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SASH1 | c.3181C>T p.L1061F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SBNO1 | c.3048+1G>A p.X1016_splice (on ENST00000420886; = p.X1015_splice on NM_018183.5) | Splice Site (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- TXNRD1 | c.1727T>C p.I576T (on ENST00000525566 / NM_001093771.3; = p.I478T on NM_003330.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ACSF2 | c.141G>A p.V47= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs369904885; called by muse, mutect2, varscan2
- ARRDC4 | c.762G>C p.V254= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- CHIT1 | c.1224T>C p.P408= | Silent (SNP) | VAF 76/102 reads (75%) | called by muse, mutect2, varscan2
- CUBN | c.9784T>C p.L3262= | Silent (SNP) | VAF 20/30 reads (67%) | called by mutect2, varscan2
- DNAH11 | c.12264C>T p.H4088= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs368428210; called by mutect2, varscan2
- H3C8 | c.181C>T p.L61= | Silent (SNP) | VAF 167/247 reads (68%) | catalogued as rs777500543; called by muse, mutect2, varscan2
- IGHJ6 | c.42C>A p.T14= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs370399988; called by muse, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as rs367953381; called by muse, varscan2
- IGLV2-23 | c.318T>C p.D106= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs552766170; called by muse, varscan2
- IGLV3-1 | c.102A>C p.G34= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs185369291; called by muse, varscan2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs376421895; called by muse, mutect2, varscan2
- NAV2 | c.6546G>A p.L2182= (on ENST00000396087 / NM_001244963.2; = p.L2123= on NM_145117.5) | Silent (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- PPP2R1A | c.450C>G p.L150= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- SLC35B2 | c.480A>C p.R160= | Silent (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
- SP6 | c.54C>T p.H18= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs771405562; called by muse, mutect2, varscan2
- SPATA31D1 | c.1071C>G p.T357= | Silent (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- ZSCAN16 | c.264G>A p.Q88= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- ABCC1 | c.*425T>G | 3'UTR (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- AC004947.2 | n.368A>G | RNA (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.-151+1795G>T | Intron (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- AGRN | c.5652-244C>G | Intron (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- AL353743.4 | n.1262T>G | RNA (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- ARL14 | c.-101C>T | 5'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- ATP2B3 | c.*260del | 3'UTR (DEL) | VAF 3/23 reads (13%) | called by pindel, varscan2
- BEND4 | c.*6370T>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- C11orf87 | c.*20C>T | 3'UTR (SNP) | VAF 152/514 reads (30%) | called by muse, mutect2, varscan2
- CADM1 | c.*1877T>A | 3'UTR (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- CAMK4 | c.*3589T>C | 3'UTR (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- CBX7 | c.*296C>T | 3'UTR (SNP) | VAF 22/62 reads (35%) | catalogued as rs539709412, COSV53359607; called by muse, mutect2, varscan2
- CCDC136 | c.-27C>T | 5'UTR (SNP) | VAF 33/116 reads (28%) | catalogued as COSV52804790; called by muse, mutect2, varscan2
- CCDC138 | c.-41G>A | 5'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1369738676; called by muse, mutect2
- CCL28 | c.*138G>A | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CPNE2 | c.*105C>T | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- CSTF2T | c.*683C>T | 3'UTR (SNP) | VAF 36/91 reads (40%) | catalogued as rs1333465801; called by muse, mutect2, varscan2
- CXCL14 | c.*307dup | 3'UTR (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- CYHR1 | c.247-2060C>T | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- DCAF8L1 | c.*1439G>A | 3'UTR (SNP) | VAF 22/26 reads (85%) | catalogued as rs1170272755; called by muse, mutect2, varscan2
- DRC7 | c.*174A>G | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50201578 del AA | 3'Flank (DEL) | VAF 25/46 reads (54%) | called by mutect2, pindel, varscan2
- EMP2 | c.*273A>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*731G>A | 3'UTR (SNP) | VAF 50/77 reads (65%) | called by muse, mutect2, varscan2
- ERMN | c.*458C>T | 3'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- FOXK1 | c.*7799G>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs1276018383; called by muse, mutect2, varscan2
- FOXP2 | c.169-35672G>T | Intron (SNP) | VAF 81/303 reads (27%) | called by muse, mutect2, varscan2
- FYB1 | c.1394+52G>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- GCSAM | c.*2458G>T | 3'UTR (SNP) | VAF 38/117 reads (32%) | called by muse, mutect2, varscan2
- GDF5 | c.*132C>T | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- GFM1 | c.*505_*511del | 3'UTR (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- GREM1 | c.*993G>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- IGFN1 | c.1242-1423A>T | Intron (SNP) | VAF 84/123 reads (68%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.-35A>T | 5'UTR (SNP) | VAF 25/25 reads (100%) | called by muse, varscan2
- IGHV3-21 | c.-45A>G | 5'UTR (SNP) | VAF 26/26 reads (100%) | called by muse, varscan2
- IL18R1 | c.*597C>T | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- IL6R | c.*2362A>C | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- ILK | c.89+184del | Intron (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel
- IRAG1 | c.-72G>A | 5'UTR (SNP) | VAF 11/23 reads (48%) | catalogued as rs189418308; called by muse, mutect2, varscan2
- KCNJ5 | chr11:128917344 C>A | 3'Flank (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- KRT18P20 | n.170C>T | RNA (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- LINC00637 | n.424G>C | RNA (SNP) | VAF 119/205 reads (58%) | called by muse, mutect2, varscan2
- LRRC8D | c.*433A>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- LUZP2 | c.*3587A>T | 3'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- MALT1 | c.*2919G>C | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- MAP1B | chr5:72107264 T>C | 5'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- MIER1 | c.*2381A>C | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by mutect2, varscan2
- MMP16 | c.*9023C>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- NACA | c.382-60_382-59del | Intron (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- NDUFAF2 | chr5:61153085 T>G | 3'Flank (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- NELL1 | c.*22G>A | 3'UTR (SNP) | VAF 94/304 reads (31%) | catalogued as rs201011404, COSV54252916; called by muse, mutect2, varscan2
- NMUR2 | c.*295C>G | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- NR1H3 | chr11:47248337 A>T | 5'Flank (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57043630; called by muse, mutect2
- PCGF3 | c.*2196G>A | 3'UTR (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- PFKP | c.1684-747C>T | Intron (SNP) | VAF 23/35 reads (66%) | catalogued as rs1276065463; called by muse, mutect2, varscan2
- PHF21A | c.1606-38A>G | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- RBBP6 | c.304-111A>G | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- RFFL | c.*1735C>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- RNF125 | c.*3832_*3851del | 3'UTR (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel
- RPS6KC1 | c.*1454C>G | 3'UTR (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- S100A14 | c.*491G>A | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- SCARF1 | c.*215G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- SCLT1 | c.290+2261T>A | Intron (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- SDK2 | c.*1378C>T | 3'UTR (SNP) | VAF 13/64 reads (20%) | catalogued as rs976320330; called by muse, mutect2, varscan2
- SERPINA3 | c.644-378C>T | Intron (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- SLAMF1 | chr1:160647272 C>T | 5'Flank (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2
- SNTB1 | c.-38C>T | 5'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- SPIN1 | c.*3120G>A | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- SSU72 | c.-95C>T | 5'UTR (SNP) | VAF 7/16 reads (44%) | catalogued as rs1462961862; called by muse, mutect2, varscan2
- STMN4 | c.*413C>T | 3'UTR (SNP) | VAF 21/47 reads (45%) | catalogued as rs1021276987; called by muse, mutect2, varscan2
- SYNM | c.*2152G>T | 3'UTR (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- TAP2 | c.*3220A>G | 3'UTR (SNP) | VAF 16/57 reads (28%) | catalogued as rs1046735687; called by muse, mutect2, varscan2
- TCEAL5 | c.*190G>T | 3'UTR (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- TCF4 | c.549+28520A>G | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- TIMM44 | c.*160C>T | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- TLE6 | c.703-45A>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TMEM41A | c.*1702A>G | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- TRAF6 | chr11:36488190 A>G | 3'Flank (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- TRHDE | c.*151T>G | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- TRPC1 | c.*483_*486del | 3'UTR (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- TSLP | c.*1049C>T | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.43238-38G>A | Intron (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- UHMK1 | c.*1026C>G | 3'UTR (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- VN2R19P | chr19:58009820 G>A | 3'Flank (SNP) | VAF 25/43 reads (58%) | catalogued as rs1221342676; called by muse, mutect2, varscan2
- WDR45B | c.705-53C>T | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- WNT7B | c.*1957T>C | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.*89dup | 3'UTR (INS) | VAF 16/83 reads (19%) | catalogued as rs1050434461; called by mutect2, pindel, varscan2
